MMRF case MMRF_1153 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b9071bd7-8172-4eb2-8192-b28d4d9233a8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.5 years (21,734 days); ISS stage: I; Days to last known disease status: 1,681 days (4.6 years); Days to last follow up: 1,681 days (4.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 183 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 185 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 339 days; Days to treatment end: 875 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 974 days (2.7 years); Days to treatment end: 1,240 days (3.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,317 days (3.6 years); Days to treatment end: 1,362 days (3.7 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,317 days (3.6 years); Days to treatment end: 1,380 days (3.8 years).
   Treatment given: Therapeutic agents: Daratumumab + Lenalidomide + Prednisone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,389 days (3.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -34 (ECOG 1): M Protein 5.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 58.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 63.8 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 3.23 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.84 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 8.2 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.041 mg/dL.
- Day 92 (ECOG 1): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.96 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 8.86 mmol/L.
- Day 182: M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 3.43 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.25 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.56 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.37 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 4.79 mmol/L.
- Day 302 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 2.97 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 8.64 mmol/L.
- Day 421: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.2 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 6.38 mmol/L.
- Day 477 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.42 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 5.39 mmol/L.
- Day 561 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 3.31 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.65 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.05 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 6.05 mmol/L.
- Day 652 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 4.4 mmol/L.
- Day 764 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 3.49 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.34 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.93 mmol/L.
- Day 890 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 4.6 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 3.16 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6.66 mmol/L.
- Day 967 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 0.24 g/L; Immunoglobulin A 3.98 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.47 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 6.38 mmol/L.
- Day 1,023 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.75 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 1,135 (ECOG 0): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 6.6 mmol/L.
- Day 1,254: M Protein 1.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.01 mmol/L.
- Day 1,317: M Protein 1.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 27.6 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 6.57 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 8.3 g/dL; Glucose 4.84 mmol/L.
- Day 1,409 (ECOG 0): M Protein 1.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.53 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.01 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.
- Day 1,527 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 3.97 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 1.3 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.9 mmol/L.
- Day 1,625 (ECOG 0): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 2.46 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.92 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 4.79 mmol/L.
- Day 1,681 (ECOG 0): M Protein 0.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 2.07 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.76 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.87 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.5 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -34: Weight: 79 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1153_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_1153_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
- Sample MMRF_1153_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,317 days (3.6 years).
